Somatic mutation profile of tumor specimen TARGET-10-PANVAW-09A (aliquot TARGET-10-PANVAW-09A-01D) from TARGET case TARGET-10-PANVAW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,358 days).
Specimen TARGET-10-PANVAW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66f359a8-f4ca-41ce-b4a8-6234c2e1299a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVAW-10A (Blood Derived Normal), aliquot TARGET-10-PANVAW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7affae54-9306-4faa-8ae3-3652fe77aec4

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABO | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1211406855; called by muse, mutect2
- NRG1 | c.1580C>T p.T527M (on ENST00000405005 / NM_013964.5; = p.T532M on NM_013956.5) | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320798326, COSV55149267; called by muse, mutect2, varscan2
- PRICKLE2 | c.1972G>A p.A658T (on ENST00000295902; = p.A602T on NM_198859.4) | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs772970017, COSV55766441, COSV55770710; called by muse, mutect2, varscan2
- FAM160A2 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IGHV3-43 | chr14:106470263 TAT>GGGCAATATAA | Missense Mutation (INS) | VAF 49/110 reads (45%) | called by pindel, varscan2*
- PLS1 | c.1112del p.L371Cfs*18 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- SMG1 | c.10642C>T p.Q3548* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- SLC6A2 | c.459C>T p.N153= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs763058744, COSV54924864; called by muse, mutect2
- ABCA3 | c.613+12G>A | Intron (SNP) | VAF 16/35 reads (46%) | catalogued as rs777275480; called by muse, mutect2, varscan2
- CYB5R1 | c.475+25C>A | Intron (SNP) | VAF 23/66 reads (35%) | catalogued as rs560661840; called by muse, mutect2, varscan2
- PSTPIP1 | c.838+16C>T | Intron (SNP) | VAF 24/75 reads (32%) | catalogued as rs781423711, COSV99143621; called by muse, mutect2, varscan2
- SEC23A | c.*75C>G | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
